Gene-level copy-number profile of tumor specimen TCGA-EJ-A65J-01A from TCGA case TCGA-EJ-A65J, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.7 years (22,904 days).
Specimen TCGA-EJ-A65J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.f2da47c9-4500-4867-98db-8068831247d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-A65J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a23d9530-b3ed-47e3-ae47-fcf0be3b4bdd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 28; copy number 2: 4,396; copy number 3: 500; copy number 4: 52,095; copy number 5: 1,138; copy number 6: 4; copy number 7: 14; copy number 8: 1,519; copy number 9: 103.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-A65J-01A-11D-A30W-01): tumor purity 0.85, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:84,230,666–84,259,960, 1 gene (within-gene range 0–2): RGR.
- chr10:84,267,747–84,294,659, 1 gene: LINC00858.
- chr10:87,859,158–88,851,844, 19 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 103 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,828,736–176,867,838, 31 genes, copy number 9 (within-gene range 8–9): ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147.
- chr3:187,368,385–193,697,811, 72 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
